Somatic mutation profile of tumor specimen TCGA-RC-A7S9-01A (aliquot TCGA-RC-A7S9-01A-11D-A33Q-10) from TCGA case TCGA-RC-A7S9, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 47.6 years (17,403 days).
Specimen TCGA-RC-A7S9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56c9f23a-63ec-4a9f-bc4c-cfd4f36d18c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RC-A7S9-10A (Blood Derived Normal), aliquot TCGA-RC-A7S9-10A-02D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79e8a674-d7d8-49d0-bdab-8e05102c61ab

The open-access MAF lists 60 somatic variants for this specimen: 50 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 38, Silent 10, Frame Shift Ins 3, Frame Shift Del 3, Splice Site 3, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1389+2T>C p.X463_splice | Splice Site (SNP) | VAF 47/69 reads (68%) | hotspot (GDC flag); catalogued as CS023834, COSV57314766; called by muse, mutect2, varscan2
- ACOX2 | c.236C>A p.A79D | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100250200; called by muse, mutect2, varscan2
- ACOX2 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as rs747182843, COSV100250201; called by muse, mutect2, varscan2
- AGBL5 | c.1895C>A p.S632Y | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59937171; called by muse, mutect2, varscan2
- ALG9 | c.778A>G p.I260V | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1555140947, COSV67644818; called by muse, mutect2, varscan2
- AOX1 | c.3539A>G p.H1180R | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs1559261369, COSV53496551; called by muse, mutect2, varscan2
- APOB | c.9991A>G p.I3331V | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as COSV51942699; called by muse, mutect2, varscan2
- ATP6V1B2 | c.563A>C p.K188T | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52354358; called by muse, mutect2, varscan2
- BTNL2 | c.527A>G p.Y176C | Missense Mutation (SNP) | VAF 95/162 reads (59%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); catalogued as COSV66631192; called by muse, mutect2, varscan2
- C6orf58 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61666874; called by muse, mutect2, varscan2
- CBLB | c.866G>T p.C289F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51430868; called by muse, mutect2, varscan2
- CHD4 | c.2981C>T p.S994F (on ENST00000357008 / NM_001363606.2; = p.S1007F on NM_001273.5) | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58905043; called by muse, mutect2, varscan2
- CNTNAP2 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 32/109 reads (29%) | catalogued as COSV62214377; called by muse, mutect2, varscan2
- COL7A1 | c.6808G>T p.D2270Y | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as COSV60398082; called by muse, mutect2, varscan2
- CREB3L3 | c.976-1G>A p.X326_splice | Splice Site (SNP) | VAF 26/107 reads (24%) | catalogued as rs112561919, COSV50226868; called by muse, mutect2, varscan2
- CUL9 | c.2263C>T p.L755F | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV52731060; called by muse, mutect2, varscan2
- DNAH1 | c.790A>G p.M264V | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV70231859; called by muse, mutect2, varscan2
- FOXD4L3 | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 61/323 reads (19%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.02); catalogued as COSV61551534; called by muse, mutect2, varscan2
- FSTL5 | c.442A>C p.M148L | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60208655; called by muse, mutect2, varscan2
- GATA6 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV52526619; called by muse, mutect2, varscan2
- GLYAT | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV53539861; called by muse, mutect2, varscan2
- GPR137B | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs199613305, COSV100858353, COSV63991293; called by muse, mutect2, varscan2
- GRM8 | c.1685C>G p.P562R | Missense Mutation (SNP) | VAF 59/105 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58843949; called by muse, mutect2, varscan2
- LAMB2 | c.2489-1G>T p.X830_splice | Splice Site (SNP) | VAF 38/114 reads (33%) | catalogued as COSV59735361; called by muse, mutect2, varscan2
- MEP1A | c.1042T>C p.Y348H | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765458047, COSV57921312; called by muse, mutect2, varscan2
- NF1 | c.4772G>A p.S1591N (on ENST00000358273 / NM_001042492.3; = p.S1570N on NM_000267.3) | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62209974; called by muse, mutect2, varscan2
- PCDHB8 | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 99/770 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.043); catalogued as COSV50789607, COSV99177144; called by muse, mutect2, varscan2
- PREX2 | c.3336C>A p.N1112K | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55783396; called by muse, mutect2, varscan2
- RBM39 | c.1466A>G p.N489S (on ENST00000253363 / NM_001323424.2; = p.N483S on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs199587566, COSV53613577; called by muse, mutect2, varscan2
- RYR2 | c.4753C>T p.R1585C | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs528206995, COSV63679348; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN9A | c.386G>T p.S129I | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs747448727, COSV57615748; called by muse, mutect2
- SPATA46 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.01); catalogued as COSV62632473; called by muse, mutect2, varscan2
- SSUH2 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.759); catalogued as rs1283655234, COSV58031562; called by muse, mutect2, varscan2
- STYK1 | c.437T>C p.L146P | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1187103882, COSV50013973; called by muse, mutect2, varscan2
- SULT1C3 | c.521G>C p.G174A | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61252645, COSV61253621; called by muse, mutect2, varscan2
- TRPA1 | c.641T>A p.M214K | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV51566735; called by muse, mutect2, varscan2
- TUBAL3 | c.268C>A p.H90N | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV66814474; called by muse, mutect2, varscan2
- VIPAS39 | c.1285A>C p.N429H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.447); catalogued as COSV58940729; called by muse, mutect2, varscan2
- VSIG4 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV66074228; called by muse, mutect2, varscan2
- ZNF703 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV58999101; called by muse, mutect2, varscan2
- ATG16L1 | c.1252dup p.L418Pfs*37 (on ENST00000392017 / NM_030803.7; = p.L399Pfs*37 on NM_017974.4) | Frame Shift Ins (INS) | VAF 35/82 reads (43%) | called by mutect2, pindel, varscan2
- FBXO42 | c.1710_1711insG p.P571Afs*82 | Frame Shift Ins (INS) | VAF 21/35 reads (60%) | called by mutect2, pindel, varscan2
- GABRR3 | c.545C>A p.A182D | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- GTF2B | c.903del p.T302Qfs*25 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- LILRA6 | c.599dup p.Y200* | Nonsense Mutation (INS) | VAF 40/245 reads (16%) | called by pindel, varscan2
- PCLO | c.15188dup p.V5064Gfs*12 | Frame Shift Ins (INS) | VAF 66/166 reads (40%) | called by mutect2, varscan2
- REV3L | c.5063del p.G1688Dfs*4 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | called by mutect2, pindel, varscan2
- SDF4 | c.84_107del p.A29_S36del | In Frame Del (DEL) | VAF 5/24 reads (21%) | called by mutect2, varscan2
- TAF15 | c.483A>C p.Q161H (on ENST00000605844 / NM_139215.3; = p.Q158H on NM_003487.4) | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TTN | c.32548_32566delinsCTA p.V10850Lfs*10 (on ENST00000591111; = p.V9923Lfs*10 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 42/102 reads (41%) | called by pindel, varscan2*
- ACACB | c.2632C>A p.R878= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as COSV58139386; called by muse, mutect2, varscan2
- ANO8 | c.711C>A p.I237= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV50186467; called by muse, mutect2, varscan2
- CDH1 | c.1389G>A p.E463= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as COSV55736232; called by muse, mutect2, varscan2
- EPHA4 | c.540G>A p.G180= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV56037934; called by muse, mutect2, varscan2
- ITSN1 | c.4857G>A p.P1619= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as rs760597542, COSV67157313; called by muse, mutect2, varscan2
- KIAA0100 | c.363C>G p.S121= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV66494636; called by muse, mutect2, varscan2
- PCDHA10 | c.1518C>T p.Y506= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as COSV56522344; called by muse, mutect2, varscan2
- PSD3 | c.369C>T p.L123= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as COSV58973075; called by muse, mutect2, varscan2
- ZNF257 | c.912T>C p.T304= | Silent (SNP) | VAF 51/91 reads (56%) | catalogued as COSV71310124; called by muse, mutect2, varscan2
- ZNF350 | c.1377G>A p.G459= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV54709586; called by muse, mutect2, varscan2
